Gene-level copy-number profile of tumor specimen TCGA-04-1353-01A from TCGA case TCGA-04-1353, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Age at diagnosis: 64.6 years (23,611 days).
Specimen TCGA-04-1353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0836cb2f-6a21-463c-9774-4892587f1e84.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1353-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63070973-9b41-4d76-b0fc-272fb740059c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 13,877; copy number 2: 33,356; copy number 3: 10,739; copy number 4: 1,575; copy number 5: 257.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1353-01A-01D-1043-01): tumor purity 0.84, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,865,627–106,875,071, 4 genes: IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.
- chr19:53,281,559–53,316,043, 4 genes: FAM90A27P, BIRC8, FAM90A28P, VN1R6P.
- chr22:48,866,770–48,898,386, 1 gene: LINC01310.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 257 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:96,940,068–103,514,007, 256 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:103,484,208–103,484,539, 1 gene, copy number 5: RN7SKP86.

Autosomal genes at a single copy (total copy number 1): 11,459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
